Somatic mutation profile of tumor specimen MP2PRT-PAUPKG-TMP1-A (aliquot MP2PRT-PAUPKG-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUPKG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,676 days).
Specimen MP2PRT-PAUPKG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7796f0f0-19cc-4bd9-9a8e-f723d3d6497b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPKG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPKG-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/364343e6-c295-4c2a-83c4-f2a83c075626

The open-access MAF lists 18 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Nonsense Mutation 2, Silent 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC3 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 210/672 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1003355; called by muse, mutect2, varscan2
- CBLC | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 148/430 reads (34%) | catalogued as rs372975672; called by muse, mutect2, varscan2
- CCDC130 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 189/650 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs771859681, COSV99237119; called by muse, mutect2, varscan2
- EGLN3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 168/821 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs201051686; called by muse, mutect2, varscan2
- FRYL | c.8860C>T p.H2954Y | Missense Mutation (SNP) | VAF 100/368 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV51942225; called by muse, mutect2, varscan2
- GASK1A | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 193/560 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs761834645, COSV56182881; called by muse, mutect2, varscan2
- MPDZ | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.813); catalogued as rs1305161299; called by muse, mutect2
- PATJ | c.1502G>A p.R501K | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1246765514; called by muse, mutect2, varscan2
- PRKCI | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 76/225 reads (34%) | catalogued as rs866058843, COSV55521182, COSV99855778; called by muse, mutect2, varscan2
- PTK2B | c.1833C>T p.F611= | Splice Region (SNP) | VAF 88/302 reads (29%) | catalogued as rs751633425, COSV100594398; called by muse, mutect2, varscan2
- USP47 | c.3080G>A p.G1027E (on ENST00000399455 / NM_001372095.1; = p.G939E on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/269 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs945591789; called by muse, mutect2, varscan2
- ZNF707 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 305/871 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as rs563343022, COSV100690507; called by muse, mutect2, varscan2
- GBP6 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- LRRK2 | c.3291del p.F1097Lfs*10 | Frame Shift Del (DEL) | VAF 112/328 reads (34%) | called by mutect2, varscan2
- PRTG | c.3293C>A p.T1098K | Missense Mutation (SNP) | VAF 125/386 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RYR3 | c.6445G>A p.E2149K | Missense Mutation (SNP) | VAF 23/458 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ARRDC4 | c.1218C>T p.S406= | Silent (SNP) | VAF 81/293 reads (28%) | catalogued as rs372410629; called by muse, mutect2, varscan2
- OR10A4 | c.771C>A p.I257= | Silent (SNP) | VAF 80/306 reads (26%) | catalogued as rs146451877, COSV65842392; called by muse, mutect2, varscan2
